Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6227, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6227-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Nck: contents left neck
2. Oral cavity:lt.oral major resection -short medial long anterior
3. Oral Cavity: lt.posterior margin
4. Oral Cavity:lt.anterior margin
5. Oral Cavity:lt.lateral mucosa margin
6. Oral Cavity:deep muscle margin
7. Surgical Waste
8. Neck: contents rt neck
9. Lymph node: lt. facial node
10. Lymph node:lt neck III node
11. Lymph node:lt facial node

Diagnosis

1. Contents left neck.
Metastatic squamous cell carcinoma involving six of thirty-five lymph nodes (6/35).
- a. The involved lymph nodes are in levels I, II, and III.
- b. The largest involved lymph node measures 3.1 cm.
- c. Extranodal invasion is present.Submandibular gland with no pathologic changes.
2. Oral cavity; left oral resection.
Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumor diameter 5.5 cm.
- b. Tumor thickness 2.5 cm.
- c. Perineural invasion is present.
- d. No lymphovascular invasion.
- e. The tumor is close to deep tongue and posterior soft tissue margins (0.2 cm). The remaining margins are negative for tumor.
3. Left posterior margin.
Negative for tumor.
4. Left anterior margin.

[page 2 of 4]
Negative for tumor.

5. Left lateral mucosa margin.

Negative for tumor.

6. Deep muscle margin.

Negative for tumor.

7. Surgical waste.

Skin and soft tissues with no pathologic changes. (Gross examination only)

8. Contents right neck.

Metastatic squamous cell carcinoma involving two of twenty-one lymph nodes (2/21).

a. The involved lymph nodes are in levels II and III.

b. The largest involved lymph node measures 1.0 cm.

c. No extranodal invasion present.

Submandibular gland with no pathologic changes.

9. Left facial lymph node.

One lymph node negative for tumor (0/1).

10. Left neck III lymph node.

Soft tissues with no pathologic changes.

11. Left facial lymph node.

Two lymph nodes negative for tumor (0/2).

Synoptic Data

Specimen Type:	Resection:left oral resection
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 5.5 cm Tumor thickness: 2.5 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor
Pathologic Staging (pTNM):	pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx Number of regional lymph nodes examined: 59 Number of regional lymph nodes involved: 8 Extra-capsular extension of nodal tumor: Present pMX: Distant metastasis cannot be assessed

verified by:

Electronically

[page 3 of 4]
Gross Description

1. The specimen is labeled with the patient's name and as "contents left neck of". It consists of an oriented left neck dissection with overall dimensions of 17.0 x 1.2 x 13.5 cm. The specimen includes levels IA to IV. There is a portion of muscle measuring 4.0 x 2.0 x 0.5 cm. The submandibular gland measures 3.7 x 3.0 x 0.9 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 3.1 cm are identified in multiple levels with the largest node being in level IIA. Representative sections are submitted.

- 1A-1B multiple lymph nodes per block, level IA
- 1C submandibular gland
- 1D multiple lymph nodes, level IB
- 1E muscle
- 1F largest lymph node level IIA
- 1G one lymph node level II
- 1H multiple lymph nodes level II
- 1I-1J multiple lymph nodes per block level IIb
- 1K one lymph node level IIb
- 1L one lymph node level IIb
- 1M-1N multiple lymph nodes per block level III
- 1O one lymph node level III
- 1P one lymph node level III
- 1Q multiple lymph nodes, level IV

2. The specimen is labeled the patient's name and as "LT oral major resection short-medial long anterior". It consists of an oriented portion of left tongue, floor of mouth with overall dimensions of 6.5 cm SI x 3.9 cm ML x 8.1 cm AP. The portion of tongue measures 2.2 cm x SI 3.4 cm ML x 8.1 cm AP. The floor of mouth measures 2.0 cm SI x 4.0 cm ML x 6.0 cm AP cm. There is a tumor involving the tongue and floor of mouth. The tumor measures 3.5 cm SI x 2.5 cm ML x 5.5 cm AP. The tumor has an ulcerated center with rolled edges. The cut surface is white-tan. It is located at 0.5 cm from the lateral margin, 1.4 cm from the medial margin, 1.2 cm from the deep margin, 0.5 cm from the anterior (floor of mouth) margin, and 0.6 cm from the posterior (junction of tongue and floor of mouth) margin. The remaining tongue mucosa is unremarkable. Tissue is taken for the for the tissue bank. Representative sections are submitted.

- 2A anterior floor of mouth margin with tumor
- 2B posterior margin (junction of tongue and floor of mouth) with tumor
- 2C medial margin with tumor
- 2D lateral floor of mouth margin with tumor
- 2E dorsum of tongue with tumor
- 2F deep margin with tumor
- 2G tumor with medial margin
- 2H lateral margin with tumor and sublingual gland

3. The specimen is labeled with the patient's name and as "LT posterior tongue". It consists of a fragment of tissue measuring 1.5 x 0.9 x 0.6 cm. The specimen is submitted in toto for frozen section.

- 3A frozen section control

4. The specimen is labeled with the patient's name and as "LT anterior tongue". It consists of a fragment of tissue measuring 1.4 x 0.4 x 0.2 cm. The specimen is submitted in toto for frozen section.

- 4A frozen section control

[page 4 of 4]
5. The specimen is labeled with the patient's name and as "LT lateral margin mucosa". It consists of a fragment of tissue measuring 1.1 x 0.4 x 0.1 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "deep muscle margin". It consists of a fragment of tissue measuring 1.0 x 0.7 x 0.2 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen labeled with the patient's name and as "surgical waste". It consists of multiple pieces of adipose tissue, seven with skin on one aspect, ranging in size from 3.0 to 10.5 cm. Also received is muscle. All of the pieces are grossly appear unremarkable. No sections are taken for microscopic examination.

8. The specimen is labeled with the patient's name and as "contents RT neck". It consists of an oriented right neck dissection with overall dimensions of 10.0 SI x 2.2 ML x 8.7 AP cm. The specimen includes levels I to III. The submandibular gland measures 4.5 x 2.8 x 1.8 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 1.5 cm are identified in multiple levels with the largest nodes in level II. Representative sections are submitted.

8A submandibular gland

8B-8C multiple lymph nodes per block level I

8D-8H multiple lymph nodes per block level II

8I one lymph node level II

8J one lymph node level II

8K multiple lymph nodes level III

9. The specimen is labeled with the patient's name and as "LT facial node #16". It contains two pieces of adipose tissue measuring 0.7 and 1.8 cm each in maximum dimension. A single lymph node, is identified within the largest piece of adipose tissue.

9A one lymph node

10. The specimen is labeled with the patient's name and as "LT level III node neck". It consists of a piece of adipose tissue measuring 1.5 x 0.5 x 0.1 cm. No lymph nodes are grossly identified.

10A specimen in toto

11. The specimen is labeled with the patient's name and as "LT facial node #2". It consists of a piece of adipose tissue measuring 1.8 x 1.2 x 0.4 cm. Multiple lymph nodes ranging from 0.3 to 0.7 cm in maximum dimension are identified.

11A multiple lymph nodes

Quick Section Diagnosis

3. Left posterior margin: Negative for malignancy

4. Left anterior margin: Negative for malignancy

5. Left lateral margin: Negative for malignancy

6. Deep muscle margin: Negative for malignancy

Source: NCI Genomic Data Commons file 870e3e8e-2562-4bb4-9293-1bf71adf80e1 (TCGA-CQ-6227.BBBD981A-4264-45D3-BEB2-CEAC32D3C55F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).